MMRF case MMRF_2475 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d7c51323-ed06-4aeb-b8dc-cc2e97749fd1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 47.4 years (17,313 days); ISS stage: I; Days to last known disease status: 688 days (1.9 years); Days to last follow up: 688 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 131 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 222 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 423 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 688.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -34 (ECOG 1): M Protein 1.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 202 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 6.94 g/L; Immunoglobulin A 14.3 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.03 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 4.6 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 8.1 g/dL; Glucose 6.77 mmol/L.
- Day 60 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin A 0.35 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.9 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 4.95 mmol/L.
- Day 162 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 6.37 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.58 mmol/L; Albumin 47 g/L; Total Protein 6.8 g/dL; Glucose 5.28 mmol/L.
- Day 250 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin A 0.8 g/L; Hemoglobin 9.42 mmol/L; Leukocytes 5 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 330 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin A 0.96 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 430: Serum Free Immunoglobulin Light Chain, Kappa 3.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin A 1.23 g/L; Beta 2 Microglobulin 0.32 µg/mL; Hemoglobin 8.99 mmol/L; Leukocytes 5.35 ×10⁹/L; Absolute Neutrophil 3.18 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Glucose 6.44 mmol/L.
- Day 491: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin A 1.76 g/L; Beta 2 Microglobulin 0.41 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 5.7 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 40.4 g/L; Glucose 5.06 mmol/L.
- Day 607: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin A 1.77 g/L; Hemoglobin 9.24 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 4.4 mmol/L.
- Day 683: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Immunoglobulin A 1.82 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.3 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -34: Weight: 119 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2475_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -34 days.
- Sample MMRF_2475_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -34 days.
